Somatic mutation profile of cancer-model specimen HCM-BROD-1186-C64-85B (3D Organoid, passage 5; aliquot HCM-BROD-1186-C64-85B-01D-A881-36), derived from the primary tumor of HCMI case HCM-BROD-1186-C64, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 50.0 years (18,276 days).
Specimen HCM-BROD-1186-C64-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 184682fb-5b34-4b84-b415-9762bf668193.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-1186-C64-11A (Solid Tissue Normal), aliquot HCM-BROD-1186-C64-11A-11D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af379d32-1ca0-44b8-b05c-212ae3752e08

The open-access MAF lists 94 somatic variants for this specimen: 68 protein-altering or splice-affecting, 20 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 20, Intron 6, Nonsense Mutation 5, Frame Shift Del 3, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 50/307 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.787A>G p.T263A | Missense Mutation (SNP) | VAF 134/334 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV56102873; called by muse, mutect2, varscan2
- ARID1A | c.5531G>A p.W1844* | Nonsense Mutation (SNP) | VAF 25/533 reads (5%) | catalogued as COSV61371432; called by muse, mutect2
- ARMCX2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 25/328 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as rs782242885, COSV57530775; called by muse, mutect2
- C10orf71 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 26/405 reads (6%) | catalogued as rs773106985; called by muse, mutect2
- CACNA1I | c.4346G>A p.R1449H | Missense Mutation (SNP) | VAF 17/422 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1472537135, COSV60810026; called by muse, mutect2
- CARD11 | c.2960C>A p.T987K | Missense Mutation (SNP) | VAF 43/554 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.056); catalogued as rs376039195; called by muse, mutect2
- COL6A3 | c.4060G>C p.D1354H | Missense Mutation (SNP) | VAF 29/532 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.749); catalogued as rs559206141, COSV55106892, COSV55109871; called by muse, mutect2
- HARS1 | c.1278G>C p.K426N | Missense Mutation (SNP) | VAF 149/312 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV56906176; called by muse, mutect2, varscan2
- MYO1G | c.1217G>C p.S406T | Missense Mutation (SNP) | VAF 149/291 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51854538; called by muse, mutect2, varscan2
- N4BP2L2 | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57230597; called by muse, mutect2, varscan2
- NDFIP2 | c.654C>G p.D218E | Missense Mutation (SNP) | VAF 108/227 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54527542; called by muse, mutect2, varscan2
- PBRM1 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 169/217 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56304081, COSV56308416; called by muse, mutect2, varscan2
- PROB1 | c.1592T>C p.I531T | Missense Mutation (SNP) | VAF 261/559 reads (47%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs535719316; called by muse, mutect2, varscan2
- PTPRN2 | c.2443G>A p.A815T | Missense Mutation (SNP) | VAF 176/376 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as rs748139505, COSV67028084; called by muse, mutect2, varscan2
- SEZ6L | c.2601G>A p.S867= | Splice Region (SNP) | VAF 18/173 reads (10%) | catalogued as rs747361013, COSV50660737; called by muse, mutect2, varscan2
- SLC22A31 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 186/425 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs1282082023, COSV57024045; called by muse, mutect2, varscan2
- TUT7 | c.4103G>T p.R1368L | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as COSV52896271; called by muse, mutect2
- AAK1 | c.2123C>A p.A708D | Missense Mutation (SNP) | VAF 22/310 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- AHNAK | c.13162C>T p.P4388S | Missense Mutation (SNP) | VAF 63/490 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ANXA4 | c.148C>A p.Q50K | Missense Mutation (SNP) | VAF 196/486 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ATP2B4 | c.2056A>C p.K686Q | Missense Mutation (SNP) | VAF 75/286 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BUB1B | c.2765T>G p.L922R | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.323); called by muse, mutect2
- CDC14A | c.851G>T p.R284I | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK5RAP3 | c.124A>G p.N42D | Missense Mutation (SNP) | VAF 131/299 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- CHD9 | c.1679A>C p.E560A | Missense Mutation (SNP) | VAF 208/472 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CNTRL | c.3430T>C p.Y1144H | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- CYTH3 | c.677A>G p.N226S | Missense Mutation (SNP) | VAF 172/375 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- DAGLA | c.508A>C p.T170P | Missense Mutation (SNP) | VAF 157/365 reads (43%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- EHBP1 | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 47/308 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM110A | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 182/716 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FAM110A | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 183/716 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM71D | c.1008C>A p.N336K | Missense Mutation (SNP) | VAF 24/321 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); called by muse, mutect2
- FAT3 | c.3668A>T p.E1223V | Missense Mutation (SNP) | VAF 156/336 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- FAT4 | c.3765A>C p.E1255D | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FER1L6 | c.3565A>T p.K1189* | Nonsense Mutation (SNP) | VAF 85/211 reads (40%) | called by muse, mutect2, varscan2
- FSTL5 | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2
- GPATCH2L | c.1058del p.N353Ifs*102 | Frame Shift Del (DEL) | VAF 137/264 reads (52%) | called by mutect2, pindel, varscan2
- HAUS7 | c.470G>C p.C157S | Missense Mutation (SNP) | VAF 180/373 reads (48%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HNRNPA3 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 159/353 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- HOOK3 | c.1514A>T p.E505V | Missense Mutation (SNP) | VAF 106/242 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- IPO9 | c.1075G>T p.E359* | Nonsense Mutation (SNP) | VAF 106/196 reads (54%) | called by mutect2, varscan2
- IPO9 | c.1076A>T p.E359V | Missense Mutation (SNP) | VAF 113/210 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- LRFN3 | c.1651G>A p.V551I | Missense Mutation (SNP) | VAF 57/833 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- LTO1 | c.623A>C p.Q208P | Missense Mutation (SNP) | VAF 147/274 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MAML2 | c.3218G>A p.R1073K | Missense Mutation (SNP) | VAF 16/546 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.073); called by muse, mutect2
- MIGA1 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 11/278 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2
- OR8D4 | c.179A>T p.Y60F | Missense Mutation (SNP) | VAF 31/560 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- PIGV | c.764T>G p.F255C | Missense Mutation (SNP) | VAF 21/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PLPPR5 | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RFPL1 | c.700A>G p.T234A | Missense Mutation (SNP) | VAF 213/502 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- RNF43 | c.125_127del p.A42del | In Frame Del (DEL) | VAF 132/359 reads (37%) | called by pindel, varscan2
- RTN4RL2 | c.1048G>A p.D350N | Missense Mutation (SNP) | VAF 39/829 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); called by muse, mutect2
- SCARA3 | c.112C>A p.P38T | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SDC4 | c.214_229del p.S72Kfs*9 | Frame Shift Del (DEL) | VAF 82/343 reads (24%) | called by mutect2, pindel, varscan2
- SETD2 | c.1302C>A p.Y434* | Nonsense Mutation (SNP) | VAF 134/155 reads (86%) | called by mutect2, varscan2
- SLC35F4 | c.954G>A p.M318I (on ENST00000339762 / NM_001352015.2; = p.M282I on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TASOR2 | c.1588G>T p.D530Y | Missense Mutation (SNP) | VAF 171/289 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TMEM39A | c.757A>C p.N253H | Missense Mutation (SNP) | VAF 154/171 reads (90%) | SIFT tolerated (0.53); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TOPORS | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 47/228 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TRIM29 | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 37/261 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTF1 | c.1094G>T p.S365I | Missense Mutation (SNP) | VAF 109/252 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYW1 | c.121G>C p.V41L | Missense Mutation (SNP) | VAF 27/258 reads (10%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UBASH3B | c.1181G>T p.R394M | Missense Mutation (SNP) | VAF 175/337 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VHL | c.445_449delinsT p.A149Lfs*9 | Frame Shift Del (DEL) | VAF 90/95 reads (95%) | called by pindel, varscan2*
- VPS13D | c.12553C>A p.L4185I | Missense Mutation (SNP) | VAF 49/439 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- ZNF233 | c.1031G>A p.C344Y | Missense Mutation (SNP) | VAF 195/418 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- ZZEF1 | c.5050C>G p.L1684V | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); called by muse, mutect2
- ANGPTL2 | c.1062T>A p.I354= | Silent (SNP) | VAF 141/263 reads (54%) | called by muse, mutect2, varscan2
- ARAP3 | c.2394G>A p.G798= | Silent (SNP) | VAF 199/646 reads (31%) | called by muse, mutect2, varscan2
- BEND5 | c.1065C>A p.V355= | Silent (SNP) | VAF 179/286 reads (63%) | called by muse, mutect2, varscan2
- BHLHE41 | c.366G>T p.S122= | Silent (SNP) | VAF 104/242 reads (43%) | called by mutect2, varscan2
- CNTNAP3 | c.3003C>T p.S1001= | Silent (SNP) | VAF 46/787 reads (6%) | catalogued as rs1256433400; called by muse, mutect2
- DOK7 | c.1164C>T p.C388= | Silent (SNP) | VAF 152/492 reads (31%) | catalogued as rs763619811, COSV100403124; called by muse, mutect2
- DYNC1H1 | c.234G>T p.L78= | Silent (SNP) | VAF 20/430 reads (5%) | called by muse, mutect2
- FAM222B | c.219C>T p.H73= | Silent (SNP) | VAF 166/388 reads (43%) | catalogued as rs1179932267, COSV57935494; called by muse, mutect2, varscan2
- HLA-DRA | c.423G>C p.V141= | Silent (SNP) | VAF 370/842 reads (44%) | catalogued as COSV100895087; called by muse, mutect2
- IRS2 | c.2562C>T p.F854= | Silent (SNP) | VAF 36/804 reads (4%) | called by muse, mutect2
- LACTBL1 | c.414C>G p.L138= (on ENST00000618559; = p.L183= on NM_001289974.2) | Silent (SNP) | VAF 79/294 reads (27%) | called by muse, mutect2, varscan2
- LCP2 | c.507C>G p.S169= | Silent (SNP) | VAF 131/360 reads (36%) | called by muse, mutect2, varscan2
- LRRC15 | c.337C>T p.L113= | Silent (SNP) | VAF 19/486 reads (4%) | called by muse, mutect2
- OOSP2 | c.108C>T p.I36= | Silent (SNP) | VAF 132/344 reads (38%) | called by muse, mutect2, varscan2
- OR4Q2 | c.39C>T p.F13= | Silent (SNP) | VAF 29/221 reads (13%) | called by muse, mutect2, varscan2
- PSG1 | c.255C>T p.D85= | Silent (SNP) | VAF 154/400 reads (39%) | catalogued as rs1058959, COSV54944619, COSV54949080; called by muse, mutect2, varscan2
- SRPK3 | c.432C>G p.V144= | Silent (SNP) | VAF 202/545 reads (37%) | called by muse, mutect2, varscan2
- STX3 | c.429A>G p.E143= | Silent (SNP) | VAF 30/518 reads (6%) | called by muse, mutect2
- SYNJ1 | c.3180A>G p.E1060= | Silent (SNP) | VAF 76/160 reads (48%) | called by muse, mutect2, varscan2
- TRPM5 | c.1857C>T p.D619= | Silent (SNP) | VAF 184/479 reads (38%) | catalogued as rs145136134; called by muse, mutect2, varscan2
- AK2 | c.94-2818G>C | Intron (SNP) | VAF 150/268 reads (56%) | called by muse, mutect2, varscan2
- GLI4 | c.223+440C>G | Intron (SNP) | VAF 162/300 reads (54%) | called by muse, mutect2, varscan2
- ITGAX | c.430+58G>A | Intron (SNP) | VAF 159/558 reads (28%) | catalogued as rs1426894129, COSV99191643; called by muse, mutect2, varscan2
- RMDN2 | c.452+22041A>C | Intron (SNP) | VAF 73/299 reads (24%) | catalogued as COSV99307537; called by muse, mutect2, varscan2
- SORBS2 | c.684+7730C>G | Intron (SNP) | VAF 26/529 reads (5%) | called by muse, mutect2
- SPAG9 | c.590+837T>C | Intron (SNP) | VAF 97/258 reads (38%) | called by muse, mutect2, varscan2
